Gene-level copy-number profile of tumor specimen C3N-02026-02 from CPTAC case C3N-02026, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.5 years (29,420 days).
Specimen C3N-02026-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cf22a176-8f5a-404f-a915-7b761597e87a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02026-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/56f2737a-b969-4816-91e6-63fe6381c1cb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 15; copy number 2: 819; copy number 3: 3,647; copy number 4: 22,604; copy number 5: 9,842; copy number 6: 6,546; copy number 7: 8,465; copy number 8: 3,690; copy number 9: 2,376; copy number 10: 261; copy number 11: 56; copy number 13: 22; copy number 14: 7; copy number 15: 8; copy number 16: 11.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–4): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes (within-gene range 0–4): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–3): NUTM2B.
- chr15:34,358,633–34,588,503, 13 genes: LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,741 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,655,528, 7 genes, copy number 14: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27.
- chr4:49,486,926–49,589,529, 12 genes, copy number 9: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:1,225,381–1,295,068, 3 genes, copy number 11: SLC6A18, AC114291.1, TERT.
- chr5:37,811,589–37,966,964, 6 genes, copy number 11: GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1.
- chr5:42,799,880–42,887,392, 1 gene, copy number 11 (within-gene range 7–11): SELENOP.
- chr5:42,813,647–43,348,716, 22 genes, copy number 11–15: AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1.
- chr5:43,483,913–45,895,970, 27 genes, copy number 11–16: AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:391,752–48,214,794, 1,324 genes, copy number 9–10 (broad region; genes not listed).
- chr7:4,682,295–29,742,594, 415 genes, copy number 9 (broad region; genes not listed).
- chr7:30,424,527–35,907,105, 85 genes, copy number 9 (broad region; genes not listed).
- chr7:69,594,793–69,597,493, 1 gene, copy number 9: CT66.
- chr7:78,017,055–79,453,667, 1 gene, copy number 9 (within-gene range 8–9): MAGI2.
- chr7:78,170,195–95,615,132, 200 genes, copy number 9 (broad region; genes not listed).
- chr7:143,571,801–143,730,409, 7 genes, copy number 11: CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C.
- chr20:24,679,547–32,743,567, 127 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr22:15,282,557–15,722,608, 22 genes, copy number 13: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1.
- chr22:16,428,947–21,982,813, 289 genes, copy number 9–11 (broad region; genes not listed).
- chr22:27,748,277–33,058,381, 192 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
